Somatic mutation profile of tumor specimen C3N-04275-04 (aliquot CPT0245300006) from CPTAC case C3N-04275, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 62.0 years (22,645 days).
Specimen C3N-04275-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b592683b-5643-4801-8024-a663e511c6b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04275-31 (Blood Derived Normal), aliquot CPT0245340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/445cecfc-d63b-4610-8f81-1583b05f894d

The open-access MAF lists 101 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Intron 7, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, 3'Flank 2, 5'Flank 2, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP4 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906884, CM113470; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 42/451 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAMTS4 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1429740896; called by muse, mutect2
- ARFGAP1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1333161650; called by muse, mutect2
- BMP2K | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs776791274; called by muse, mutect2
- CT47B1 | c.230del p.Q77Rfs*67 | Frame Shift Del (DEL) | VAF 80/584 reads (14%) | catalogued as COSV64890552; called by mutect2, pindel, varscan2
- DMBX1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100760721; called by muse, mutect2
- DSP | c.8416G>A p.A2806T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as rs1005621727; called by muse, mutect2, varscan2
- GABRR3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs74748284; called by muse, mutect2
- HOATZ | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1170573923, COSV100239653; called by muse, mutect2, varscan2
- INSRR | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 66/674 reads (10%) | catalogued as COSV104427256; called by muse, mutect2, varscan2
- KLF5 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767847238; called by muse, mutect2, varscan2
- KLHDC7A | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 52/463 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV101272744; called by muse, mutect2, varscan2
- KTI12 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781405918; called by muse, mutect2
- MAGEB1 | c.1033C>A p.H345N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV66776292; called by muse, mutect2, varscan2
- MCM6 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.619); catalogued as rs755370513; called by muse, mutect2
- MUC17 | c.5011T>C p.S1671P | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs370830745; called by muse, mutect2
- NSD1 | c.4927T>G p.C1643G | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1211947; called by muse, mutect2, varscan2
- NUP205 | c.4888A>G p.I1630V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs759546768; called by muse, mutect2
- POU3F2 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV60409416; called by muse, varscan2
- REST | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs772263163; called by muse, mutect2
- RET | c.3211G>A p.G1071R | Missense Mutation (SNP) | VAF 38/409 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as rs1321512022, COSV60692165; called by muse, mutect2
- RNF213 | c.7837C>T p.R2613C | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1468761957; called by muse, mutect2
- RNF213 | c.8179C>T p.R2727W | Missense Mutation (SNP) | VAF 54/644 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs375688032; called by muse, mutect2
- ROBO3 | c.3079del p.E1027Rfs*41 | Frame Shift Del (DEL) | VAF 26/291 reads (9%) | catalogued as rs1565315119, COSV67302588; called by mutect2*, pindel
- RPS6KA1 | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763692710; called by muse, mutect2, varscan2
- SPATA7 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.075); catalogued as COSV50420377; called by muse, mutect2
- TECPR1 | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1195867020; called by muse, mutect2, varscan2
- TONSL | c.3763C>G p.L1255V | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782249203; called by muse, mutect2
- ACSS2 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- AKNA | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 47/563 reads (8%) | called by muse, mutect2
- ARFGAP1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); called by muse, mutect2
- CACNA1E | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CDH23 | c.7940C>A p.A2647E | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLIP4 | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT6L | c.1214T>C p.L405P (on ENST00000504123 / NM_001286790.2; = p.L400P on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2
- CRABP1 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2
- CRISPLD1 | c.1132T>A p.Y378N | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRTAP | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CRYBG1 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2
- FAM120C | c.3035A>G p.Q1012R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOXN3 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2
- GPC4 | c.1344del p.E449Rfs*12 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- GRIN3A | c.1237A>C p.I413L | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- GUCY2F | c.621T>A p.S207R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ITGAM | c.3349G>A p.G1117R (on ENST00000648685 / NM_001145808.2; = p.G1116R on NM_000632.4) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ4 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- LIX1L | c.656T>A p.L219Q | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LRP1B | c.11150C>G p.S3717C | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- LYZL6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ME1 | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.807); called by muse, mutect2
- MICB | c.401A>C p.Y134S | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MKI67 | c.5911A>G p.M1971V | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MLLT6 | c.3085G>T p.A1029S | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MLLT6 | c.3086C>T p.A1029V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- NOTCH2 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRXN1 | c.2072G>T p.C691F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- OR10A4 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR8K5 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- SHANK3 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 14/479 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SPHKAP | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53BP2 | c.1394T>C p.M465T (on ENST00000343537 / NM_001031685.3; = p.M336T on NM_005426.2) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.3); called by muse, mutect2
- ULK4 | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by mutect2, varscan2
- UNC5D | c.1085-1G>C p.X362_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1582A>C p.K528Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF462 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); called by muse, mutect2
- ANKZF1 | c.102C>T p.H34= | Silent (SNP) | VAF 33/319 reads (10%) | catalogued as COSV60135795; called by muse, mutect2, varscan2
- CCNY | c.969C>A p.R323= | Silent (SNP) | VAF 19/379 reads (5%) | called by muse, mutect2
- CEP162 | c.1713A>G p.P571= | Silent (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- COL14A1 | c.2673C>T p.S891= | Silent (SNP) | VAF 51/486 reads (10%) | catalogued as rs762327640; called by muse, mutect2, varscan2
- COL7A1 | c.8151T>C p.N2717= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- CPSF2 | c.198C>T p.L66= | Silent (SNP) | VAF 31/289 reads (11%) | called by muse, mutect2, varscan2
- CTNNA2 | c.402G>T p.V134= | Silent (SNP) | VAF 33/324 reads (10%) | called by muse, mutect2, varscan2
- DNAH9 | c.1026C>A p.V342= | Silent (SNP) | VAF 43/470 reads (9%) | catalogued as COSV52340754; called by muse, mutect2
- IQGAP3 | c.3654C>T p.H1218= | Silent (SNP) | VAF 22/261 reads (8%) | catalogued as rs1448115990; called by muse, mutect2
- JADE3 | c.1338A>G p.L446= | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- KANK1 | c.1689G>A p.E563= | Silent (SNP) | VAF 40/396 reads (10%) | called by muse, mutect2
- KNDC1 | c.2025G>A p.T675= | Silent (SNP) | VAF 38/374 reads (10%) | catalogued as rs1011887974, COSV58832109; called by muse, mutect2
- MRPL16 | c.649C>A p.R217= | Silent (SNP) | VAF 32/444 reads (7%) | catalogued as COSV55697274; called by muse, mutect2
- OR4K5 | c.915C>T p.Y305= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs763784897; called by muse, mutect2
- PLEC | c.1179G>A p.S393= (on ENST00000322810 / NM_201380.4; = p.S283= on NM_000445.5) | Silent (SNP) | VAF 38/468 reads (8%) | catalogued as rs1554721865; called by muse, mutect2
- POTEC | c.747T>C p.N249= | Silent (SNP) | VAF 43/397 reads (11%) | called by muse, mutect2, varscan2
- PURA | c.144C>G p.G48= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as rs1357882015, COSV58761907; called by muse, mutect2
- RNF149 | c.1056C>T p.D352= | Silent (SNP) | VAF 51/425 reads (12%) | catalogued as rs141226979; called by muse, mutect2, varscan2
- SCML4 | c.372C>T p.P124= | Silent (SNP) | VAF 30/369 reads (8%) | catalogued as rs751899100, COSV100940348; called by muse, mutect2
- TEP1 | c.7488A>G p.E2496= | Silent (SNP) | VAF 69/460 reads (15%) | called by muse, mutect2, varscan2
- ADSS1 | c.193-4937G>T | Intron (SNP) | VAF 23/261 reads (9%) | called by muse, mutect2
- C11orf49 | chr11:47164115 C>A | 3'Flank (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- C11orf49 | chr11:47164117 G>A | 3'Flank (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- KPNA1 | c.432+3464C>T | Intron (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- KRBA1 | c.-31G>A | 5'UTR (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- NCAM1 | c.2131+2548C>T | Intron (SNP) | VAF 19/218 reads (9%) | catalogued as COSV100378548; called by muse, mutect2
- NECAB1 | c.*3434T>C | 3'UTR (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- OFCC1 | n.286G>A | RNA (SNP) | VAF 18/127 reads (14%) | catalogued as rs1055388892; called by mutect2, varscan2
- RBM12B | c.-78+504A>T | Intron (SNP) | VAF 59/555 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159818 G>A | 5'Flank (SNP) | VAF 38/390 reads (10%) | catalogued as rs1250897218; called by muse, mutect2, varscan2
- RNF175 | c.764+116C>T | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- TLCD3B | chr16:30035437 C>A | 5'Flank (SNP) | VAF 21/238 reads (9%) | catalogued as rs762872407; called by muse, mutect2
- TMEM230 | c.-16+69G>T | Intron (SNP) | VAF 38/427 reads (9%) | called by muse, mutect2
- TTN | c.10303+2582A>G | Intron (SNP) | VAF 38/360 reads (11%) | called by muse, mutect2, varscan2
- ZNF849P | n.975G>A | RNA (SNP) | VAF 32/254 reads (13%) | called by muse, varscan2
